Somatic mutation profile of tumor specimen TCGA-DX-A6BH-01A (aliquot TCGA-DX-A6BH-01A-12D-A307-09) from TCGA case TCGA-DX-A6BH, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 34.9 years (12,742 days).
Specimen TCGA-DX-A6BH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3bfbed89-fe58-42c1-bcb1-62c584431fdd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A6BH-10A (Blood Derived Normal), aliquot TCGA-DX-A6BH-10A-01D-A307-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3797153b-25cf-4fe5-8fde-7efbbc8827fc

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 9, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEP112 | c.52G>C p.D18H | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101211102; called by muse, mutect2
- DTX3 | c.769G>A p.G257R | Missense Mutation (SNP) | VAF 299/675 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99678267; called by muse, mutect2, varscan2
- FLNA | c.2326G>A p.G776S | Missense Mutation (SNP) | VAF 94/136 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100774232; called by muse, mutect2, varscan2
- GJD2 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.925); catalogued as rs775572644, COSV51748301, COSV51750051; called by muse, mutect2, varscan2
- MTTP | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.061); catalogued as rs780767739, COSV99645532; called by muse, mutect2, varscan2
- OR8B8 | c.643T>C p.F215L | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.12); catalogued as COSV100045230; called by muse, mutect2
- RBMXL2 | c.125A>G p.D42G | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100182524; called by muse, mutect2
- RTL1 | c.3715G>A p.D1239N | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.949); catalogued as rs775741559, COSV66017479; called by muse, mutect2, varscan2
- SLC17A6 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.158); catalogued as COSV54135722; called by muse, mutect2
- FAM163A | c.267G>T p.G89= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV100523157; called by muse, mutect2, varscan2
- NEURL4 | c.3603C>T p.L1201= | Silent (SNP) | VAF 54/114 reads (47%) | catalogued as COSV100223288; called by muse, mutect2, varscan2
